FM case AD15727 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/0b3e518d-3533-4095-9c2b-9e3e7a4a727e

Female, 65.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Tumor.
